Somatic mutation profile of tumor specimen HCM-CSHL-0511-C24-86M (aliquot HCM-CSHL-0511-C24-86M-01D-A937-36) from HCMI case HCM-CSHL-0511-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 47.4 years (17,331 days).
Specimen HCM-CSHL-0511-C24-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c95118-6042-4d45-bc8c-fcde8b97bf15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0511-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0511-C24-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fddd5801-83da-46a3-a47e-3ddc31b9ac52

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 1, Splice Site 1, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 292/306 reads (95%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 486/488 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200512939; called by muse, mutect2, varscan2
- ACSM2A | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 305/313 reads (97%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs752798612; called by muse, mutect2, varscan2
- ACVR2B | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 449/451 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs199622012; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 410/410 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs774699404; called by muse, mutect2, varscan2
- COL6A5 | c.4309G>A p.G1437R | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs12489323, COSV55205665; called by muse, mutect2, varscan2
- EDEM3 | c.2380A>G p.K794E | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs765636238; called by muse, mutect2, varscan2
- FGD2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747641806, COSV51465153; called by muse, mutect2, varscan2
- KCNS3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 502/502 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770320711, COSV58405308; called by muse, varscan2
- LAMA2 | c.7121G>A p.S2374N | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755168390; called by muse, mutect2, varscan2
- MKX | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748997066, COSV65393548; called by muse, mutect2, varscan2
- NINL | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 596/597 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1275308034; called by muse, mutect2, varscan2
- RASA1 | c.1050-1G>C p.X350_splice | Splice Site (SNP) | VAF 146/146 reads (100%) | catalogued as COSV57203182, COSV99169670; called by muse, varscan2
- RETNLB | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 324/325 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370708969, COSV55465147; called by muse, mutect2, varscan2
- RIMBP2 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs776932506; called by muse, mutect2, varscan2
- THBS2 | c.2418C>T p.D806= | Splice Region (SNP) | VAF 34/266 reads (13%) | catalogued as rs201343909; called by mutect2, varscan2
- THSD4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 307/566 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV99964157; called by muse, mutect2, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 160/184 reads (87%) | catalogued as rs779826427; called by pindel, varscan2
- TMTC1 | c.508G>A p.V170M (on ENST00000539277 / NM_001193451.2; = p.V62M on NM_175861.3) | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139974018, COSV55490490; called by muse, mutect2, varscan2
- ZNF311 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 782/782 reads (100%) | catalogued as rs751092630; called by muse, mutect2, varscan2
- APC2 | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 559/561 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSE1L | c.1079_1081del p.E360del | In Frame Del (DEL) | VAF 179/183 reads (98%) | called by pindel, varscan2
- EMILIN2 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 476/476 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- HOXD9 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 24/800 reads (3%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP3K2 | c.1268dup p.C424Lfs*23 | Frame Shift Ins (INS) | VAF 327/453 reads (72%) | called by mutect2, pindel, varscan2
- MUC1 | c.3095_3104del p.L1032Pfs*76 (on ENST00000611571 / NM_001371720.1; = p.L245Pfs*76 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 406/426 reads (95%) | called by mutect2, varscan2
- NKRF | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- NT5DC2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 27/500 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- NUDT7 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2
- OXTR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 284/287 reads (99%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFC | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SLIT2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.095); called by muse, mutect2
- STK10 | c.1361G>C p.S454T | Missense Mutation (SNP) | VAF 580/581 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- STK11 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 542/543 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF682 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 15/501 reads (3%) | called by muse, mutect2
- ABHD10 | c.66C>T p.A22= | Silent (SNP) | VAF 581/581 reads (100%) | catalogued as rs768142804; called by muse, mutect2, varscan2
- CER1 | c.315C>T p.F105= | Silent (SNP) | VAF 259/516 reads (50%) | catalogued as COSV101097756; called by muse, mutect2, varscan2
- ERCC6L2 | c.1722A>G p.Q574= | Silent (SNP) | VAF 30/332 reads (9%) | catalogued as rs1207481621; called by muse, mutect2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 319/321 reads (99%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- OR52L1 | c.798C>T p.I266= | Silent (SNP) | VAF 52/585 reads (9%) | catalogued as rs1030251666, COSV59988452; called by muse, mutect2
- OR5M1 | c.315C>T p.I105= | Silent (SNP) | VAF 553/556 reads (99%) | catalogued as rs755863011, COSV73202247, COSV73202295; called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>T p.S738= | Silent (SNP) | VAF 440/440 reads (100%) | catalogued as COSV50758039, COSV50800092; called by muse, mutect2, varscan2
- POTEB3 | c.372C>T p.D124= | Silent (SNP) | VAF 171/264 reads (65%) | catalogued as rs1197417910; called by muse, mutect2, varscan2
- SPHKAP | c.1770G>A p.P590= | Silent (SNP) | VAF 474/476 reads (100%) | catalogued as rs141688278; called by muse, mutect2, varscan2
- AL031315.1 | c.686-2100G>A | Intron (SNP) | VAF 463/464 reads (100%) | called by muse, mutect2, varscan2
- MAF | c.*4245A>C | 3'UTR (SNP) | VAF 194/195 reads (99%) | catalogued as COSV100391602, COSV58155127; called by muse, mutect2, varscan2
